Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A4ID, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A4ID-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #:

1

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

Question papillary thyroid carcinoma. History of symptomatic papillary thyroid carcinoma.

PROCEDURE: SPGD

1. "Right level III lymph node, ?papillary carcinoma" A 2.5 x 1.8 x 1 cm portion of fibroadipose tissue containing six possible lymph nodes (0.3 to 1 cm).
- 1A. Three possible lymph nodes.
Frozen section control.
- 1B. Three possible lymph nodes.
Frozen section control. fat retained)
2. "Thyroid, stitch marks right lobe." Received fresh for procurement in a small container is a 17.8 gm thyroid with a 5 x 2.5 x 1.3 cm left lobe (inked blue), a 4.5 x 3.2 x 1.3 cm right lobe (inked green) and a 1.3 x 1.0 x 0.4 cm isthmus (inked yellow). The right lobe has a diffuse tan color and contains a 1.3 x 1.2 x 1.0 cm, tan, circumscribed, hemorrhagic, firm nodule, 0.1 cm from the thyroid capsule and a separate 0.4 x 0.5 x 0.3 cm, firm, tan, circumscribed nodule abutting the thyroid capsule. The left lobe is diffusely variegated, tan and red with no nodule. The isthmus is diffusely tan without nodules.
- 2A. Right lobe with two nodules.
- 2B-C. Remainder of larger right lobe nodule.
- 2D. Upper and lower right lobe (no nodules).
- 2E. Lower left lobe.
- 2F. Middle left lobe.
- 2G. Upper left lobe and isthmus.
3. "Level VI lymph node." Received in formalin in a small container are multiple portions of fibroadipose tissue aggregating to 4.5 x 3 x 1.5 cm and containing multiple possible lymph nodes ranging from 0.3 cm to 1.2 cm.
- 3A. Three possible lymph nodes, submitted whole.
- 3B. Five possible lymph nodes, submitted whole. Fat retained.

FROZEN SECTION REPORT

1. Fragments of benign lymph nodes.

I, [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

1CD-0-3

Carcinoma, papillary, follicular variant 8340/3
Sites: thyroid, NOS 673.9

hw 10/1/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #:

2

BIRTHDATE:

PAT TYPE:

SEX: F

ADM DATE:

OPER DATE:

PROCEDURE: SPMI

PAPILLARY THYROID CARCINOMA

Size of largest primary tumor: 1.1 cm.

Location(s): Right lobe.

Capsular Invasion: No.

Vascular Invasion: No.

Margins: Negative.

Extrathyroidal extension: No.

Lymph node metastases: No.

Extranodal extension: N.A.

LYMPH NODES

SIDE	LEVEL	#POSITIVE NODES	#TOTAL NODES
Right	III	0	6
Right	VI	0	7
Total Right All		0	13

PROCEDURE: SPDX

1. Lymph node, right level III, dissection: Six lymph nodes, negative for neoplasm.

2. Thyroid, total thyroidectomy: Papillary thyroid carcinoma (1.1 cm), well differentiated, follicular variant, confined to the thyroid. Margins negative. Please see template. 100% per TSS. JW

3. Lymph node, level VI, dissection: Seven lymph nodes, negative for neoplasm.

I, [REDACTED] the signing staff pathologist, have

10/18/12

Source: NCI Genomic Data Commons file 863619bd-6c5f-4327-8d3e-54f89c6ae643 (TCGA-KS-A4ID.2F1434B2-A474-41D3-A93D-C6DD9A946080.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).